Somatic mutation profile of tumor specimen ALCH-AFER-TTP1-A (aliquot ALCH-AFER-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-AFER, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.9 years (23,705 days).
Specimen ALCH-AFER-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a23eefb-18ac-481d-9abc-2d1eff149a76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFER-NB7-A (Blood Derived Normal), aliquot ALCH-AFER-NB7-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b270594f-defc-4925-88b8-7b43ba021a64

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Splice Region 2, Intron 1, In Frame Del 1, Splice Site 1, Silent 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.802-15_804del p.X268_splice | Splice Site (DEL) | VAF 66/274 reads (24%) | hotspot (GDC flag); called by mutect2, pindel
- ADGRB3 | c.2245G>T p.V749L | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs759276122; called by muse, mutect2, varscan2
- CAPN15 | c.2624C>T p.A875V | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs780136051; called by muse, mutect2, varscan2
- EGFR | c.2237_2256delinsTA p.E746_S752delinsV | In Frame Del (DEL) | VAF 85/328 reads (26%) | catalogued as COSV51769675, COSV51846677; called by pindel, varscan2*
- KIAA1549L | c.842C>T p.T281M (on ENST00000321505; = p.T578M on NM_012194.3) | Missense Mutation (SNP) | VAF 121/299 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.066); catalogued as rs1278446427; called by muse, mutect2, varscan2
- MPPED1 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs756953363, COSV68837822; called by muse, mutect2, varscan2
- NOTCH4 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 17/259 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs996553122, COSV100900977, COSV66685402; called by muse, mutect2
- SEMA3F | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99137178; called by muse, mutect2
- TMEM121B | c.1651G>A p.G551S | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.189); catalogued as rs1244725599; called by muse, mutect2
- WSCD2 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.844); catalogued as rs770059284, COSV54578551; called by muse, mutect2
- ZNF492 | c.33G>T p.V11= | Splice Region (SNP) | VAF 89/445 reads (20%) | catalogued as COSV71761707; called by muse, mutect2, varscan2
- FAM110A | c.165G>C p.K55N | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRFN5 | c.1337T>C p.M446T | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- MGARP | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 137/361 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- MTA1 | c.2017T>G p.S673A | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.184); called by muse, mutect2
- OR2M5 | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 167/439 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RINT1 | c.1237C>T p.H413Y | Missense Mutation (SNP) | VAF 15/448 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- SORCS3 | c.1100A>G p.H367R | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.013); called by muse, mutect2
- TMEM132A | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- WDFY3 | c.8337A>T p.G2779= | Splice Region (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- WNT10A | c.173A>T p.N58I | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- WNT3A | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2
- DNHD1 | c.12135C>T p.R4045= | Silent (SNP) | VAF 83/152 reads (55%) | catalogued as rs536552992; called by muse, mutect2, varscan2
- ETDB | chrX:135123502 C>T | 5'Flank (SNP) | VAF 15/460 reads (3%) | catalogued as rs782366478; called by muse, mutect2
- GULP1 | c.610-1840C>T | Intron (SNP) | VAF 98/358 reads (27%) | called by muse, mutect2, varscan2
- TRIP10 | c.-21G>T | 5'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as rs1176923115; called by muse, mutect2, varscan2
